TARGET case TARGET-30-PATFES — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd59495d-7059-51ec-ac5f-57b5e62ef30f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Dead; Days to death: 847 days (2.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C41.0; Tissue or organ of origin: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 1.8 years (640 days); Year of diagnosis: 2010; Days to last follow up: 847 days (2.3 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 70.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 420 days (1.1 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 420 days (1.1 years); First event: Relapse.
- Days to follow up: 847 days (2.3 years); Year of follow up: 2012.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATFES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATFES-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 847
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.32
- Histology: Unfavorable
- Site of Relapse: Primary site; Bone Marrow
